Somatic mutation profile of tumor specimen TCGA-IQ-A6SG-01A (aliquot TCGA-IQ-A6SG-01A-12D-A34J-08) from TCGA case TCGA-IQ-A6SG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.7 years (22,529 days).
Specimen TCGA-IQ-A6SG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e2c1975-e438-4f05-a013-4e8c912e06a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A6SG-10A (Blood Derived Normal), aliquot TCGA-IQ-A6SG-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9211f5e-0305-4ad8-a84c-e835cd50ac39

The open-access MAF lists 111 somatic variants for this specimen: 82 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 27, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 2, Splice Site 2, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCC11 | c.3442A>T p.M1148L | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100750982; called by muse, mutect2, varscan2
- AGL | c.2798A>G p.Y933C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756888005, COSV99649681; called by muse, mutect2, varscan2
- AHNAK | c.14887A>G p.I4963V | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs962424816, COSV99948534; called by muse, mutect2, varscan2
- AHNAK2 | c.14642A>G p.E4881G | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV100318295; called by muse, mutect2, varscan2
- ALMS1 | c.12361C>T p.R4121W | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778205604, COSV100043114; called by muse, mutect2, varscan2
- ARID4A | c.1490A>G p.D497G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV100794480; called by muse, mutect2, varscan2
- ASH2L | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV51699731; called by muse, mutect2, varscan2
- ASNSD1 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 140/288 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs755759127, COSV99641280; called by muse, mutect2, varscan2
- ASPM | c.3031A>G p.I1011V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs536317935, COSV99660778; called by muse, mutect2, varscan2
- ATRN | c.3323C>A p.P1108Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); catalogued as COSV99497511; called by muse, mutect2
- CDH9 | c.2183G>C p.S728T | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV99148626; called by muse, mutect2, varscan2
- CEACAM5 | c.1638G>T p.R546S | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99704064; called by muse, mutect2, varscan2
- CHN1 | c.998A>C p.Y333S | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789320; called by muse, mutect2
- COQ8A | c.1777G>A p.V593I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs774142518, COSV100506155; called by muse, mutect2, varscan2
- CSMD1 | c.4928C>A p.P1643H (on ENST00000520002; = p.P1642H on NM_033225.6) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100151034, COSV59346671; called by muse, mutect2, varscan2
- CTNNBL1 | c.219+2del p.X73_splice | Splice Site (DEL) | VAF 14/33 reads (42%) | catalogued as COSV63743612; called by mutect2, pindel, varscan2
- DEPP1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs374920840; called by muse, mutect2, varscan2
- DUSP21 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173628, COSV59134339; called by muse, mutect2, varscan2
- DUSP22 | c.430C>A p.H144N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100739929, COSV60525757; called by muse, mutect2, varscan2
- EPX | c.2001C>A p.S667R | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99836653; called by muse, mutect2, varscan2
- FAM180A | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.164); catalogued as COSV100647311; called by muse, mutect2, varscan2
- FSTL5 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.968); catalogued as rs202045279; called by muse, mutect2, varscan2
- GABPB2 | c.1064A>T p.E355V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV100927281; called by muse, mutect2, varscan2
- GBP7 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99643289; called by muse, mutect2, varscan2
- GGPS1 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99270532; called by muse, mutect2, varscan2
- GPX5 | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101297278; called by muse, varscan2
- HAL | c.855+1G>C p.X285_splice | Splice Site (SNP) | VAF 31/90 reads (34%) | catalogued as COSV99701387, COSV99701555; called by muse, mutect2, varscan2
- HYAL1 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV99807767; called by muse, mutect2, varscan2
- IFT81 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.242); catalogued as COSV54364282, COSV99656222; called by muse, mutect2, varscan2
- ITM2A | c.755A>C p.N252T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100964477; called by muse, mutect2
- KBTBD13 | c.1234C>A p.L412M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV101416701; called by muse, mutect2, varscan2
- KIF2B | c.1450G>C p.A484P | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52130791, COSV99275800; called by muse, mutect2, varscan2
- L1CAM | c.3080C>A p.A1027E | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100649349; called by muse, mutect2, varscan2
- LAMB4 | c.5009A>G p.K1670R | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.877); catalogued as rs756332022, COSV99224883; called by muse, mutect2, varscan2
- LMBRD1 | c.1530G>T p.W510C (on ENST00000649011; = p.W488C on NM_018368.4) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100992651; called by muse, mutect2, varscan2
- LRR1 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100023216; called by muse, mutect2, varscan2
- LRRK2 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV54171483; called by muse, mutect2, varscan2
- MAGEA10 | c.921G>T p.R307S | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54882812, COSV99726816; called by muse, mutect2, varscan2
- MAML2 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs759647780, COSV101594157; called by muse, mutect2, varscan2
- MRPL2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV52437212, COSV99432275; called by muse, mutect2, varscan2
- MRPL33 | c.150G>T p.V50= | Splice Region (SNP) | VAF 16/178 reads (9%) | catalogued as COSV99941442; called by muse, mutect2
- MTUS2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777226951, COSV70912667; called by muse, mutect2, varscan2
- MUC17 | c.7250A>T p.H2417L | Missense Mutation (SNP) | VAF 242/976 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139220229, COSV60300169; called by mutect2, varscan2
- MUC5B | c.5846C>A p.T1949N | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs369656046, COSV101500560; called by muse, mutect2
- NLRC4 | c.2696T>C p.L899P | Missense Mutation (SNP) | VAF 153/226 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100707461; called by muse, mutect2, varscan2
- NLRP10 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs201964741, COSV60781159, COSV60781793; called by muse, mutect2, varscan2
- NME8 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99553599; called by muse, mutect2, varscan2
- NOS1AP | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV100723482; called by muse, mutect2, varscan2
- NPBWR2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs751920195, COSV100871088, COSV100871132; called by muse, mutect2, varscan2
- OBSCN | c.14626G>A p.A4876T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780643259, COSV99481867; called by muse, mutect2, varscan2
- OBSCN | c.20236C>T p.R6746C | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200084844, COSV100804819; called by muse, mutect2, varscan2
- OR4K13 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100237806; called by muse, mutect2, varscan2
- PAPPA2 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1185008812, COSV100866882; called by muse, mutect2, varscan2
- PCDH11X | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs768277417, COSV53461734; called by muse, mutect2, varscan2
- PCDH11X | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1452998535, COSV100013367; called by muse, mutect2, varscan2
- PHOX2B | c.11T>G p.M4R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1553898240, COSV99891537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1L1 | c.8465A>G p.H2822R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV101005758; called by muse, mutect2, varscan2
- PPFIBP2 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs772240559, COSV55076168; called by muse, mutect2, varscan2
- PRR27 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 33/198 reads (17%) | catalogued as COSV100748870, COSV60641441; called by muse, mutect2, varscan2
- PRSS33 | c.818G>A p.W273* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99550121; called by muse, mutect2, varscan2
- RB1 | c.1303G>T p.G435* | Nonsense Mutation (SNP) | VAF 51/100 reads (51%) | catalogued as COSV57313162; called by muse, mutect2, varscan2
- RNF8 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV100009741; called by muse, mutect2, varscan2
- ROS1 | c.3971G>T p.R1324M | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV63858495; called by muse, mutect2, varscan2
- SFI1 | c.2455C>A p.L819I (on ENST00000400288 / NM_001007467.3; = p.L788I on NM_014775.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100770187; called by muse, mutect2, varscan2
- SHANK1 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV99521646; called by muse, mutect2, varscan2
- SIDT2 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs200870091, COSV54054625; called by muse, mutect2, varscan2
- SLC34A1 | c.111C>T p.V37= | Splice Region (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100184043; called by muse, mutect2, varscan2
- SLC6A17 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); catalogued as COSV100521429; called by muse, mutect2, varscan2
- SLCO6A1 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1452532537, COSV65810488; called by muse, mutect2, varscan2
- SPAG1 | c.283dup p.I95Nfs*2 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | catalogued as rs748311204, COSV99309467; called by mutect2, pindel, varscan2
- STAB2 | c.5593C>T p.R1865W | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66338332; called by muse, mutect2, varscan2
- TMIGD3 | c.317G>T p.W106L (on ENST00000369717 / NM_001081976.2; = p.W187L on NM_020683.7) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100778418, COSV63163195; called by muse, mutect2, varscan2
- TRGC2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1362256720; called by muse, mutect2, varscan2
- TRIM55 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV99396990; called by muse, mutect2, varscan2
- USP28 | c.3164A>G p.Y1055C | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV99135951; called by muse, mutect2, varscan2
- VPS13D | c.10174A>G p.I3392V | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs774537366, COSV99167638; called by muse, mutect2, varscan2
- ZNF107 | c.1070A>T p.K357I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100788440; called by muse, mutect2, varscan2
- ZNF98 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100757551; called by muse, mutect2, varscan2
- BTBD6 | c.1306del p.L436Wfs*14 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.2434_2435del p.M812Vfs*17 | Frame Shift Del (DEL) | VAF 36/199 reads (18%) | called by mutect2, pindel, varscan2
- KLC4 | c.1228del p.H410Mfs*25 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | called by pindel, varscan2
- AHCTF1 | c.3513G>A p.Q1171= (on ENST00000366508; = p.Q1145= on NM_015446.5) | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100404082; called by muse, mutect2, varscan2
- ANKEF1 | c.30C>T p.N10= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV101001052; called by muse, mutect2
- CDH3 | c.234C>T p.G78= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs201122541, COSV99868762; called by muse, mutect2, varscan2
- CEACAM5 | c.1639C>T p.L547= | Silent (SNP) | VAF 46/232 reads (20%) | catalogued as COSV99704065; called by muse, mutect2, varscan2
- CLIP1 | c.2322G>A p.L774= (on ENST00000620786 / NM_001247997.1; = p.L763= on NM_002956.2) | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as COSV100212097; called by muse, mutect2, varscan2
- COL4A6 | c.570A>T p.G190= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100564602; called by muse, mutect2, varscan2
- ETV3 | c.213G>A p.E71= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100461116; called by muse, mutect2, varscan2
- FAT4 | c.8892C>A p.S2964= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100628577; called by muse, mutect2, varscan2
- FRMPD4 | c.2691G>T p.R897= | Silent (SNP) | VAF 35/149 reads (23%) | catalogued as rs1054112619, COSV101043532; called by muse, mutect2, varscan2
- GPLD1 | c.558C>G p.V186= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100015462; called by muse, mutect2, varscan2
- GPX5 | c.300C>A p.P100= | Silent (SNP) | VAF 85/324 reads (26%) | catalogued as COSV101297277; called by muse, varscan2
- HGS | c.78G>A p.E26= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV100230624; called by muse, mutect2, varscan2
- KAT6B | c.291A>G p.G97= | Silent (SNP) | VAF 83/176 reads (47%) | catalogued as COSV99768581; called by muse, mutect2, varscan2
- LRP1 | c.6559C>T p.L2187= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1228391051; called by muse, mutect2
- NOTCH2 | c.2679C>T p.G893= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV56681329, COSV99865513; called by muse, mutect2, varscan2
- OR10G4 | c.90G>T p.L30= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs1041276506, COSV57979726; called by muse, mutect2
- OR10G7 | c.90G>T p.L30= | Silent (SNP) | VAF 25/223 reads (11%) | catalogued as COSV100389998; called by muse, mutect2, varscan2
- PAPPA2 | c.315C>T p.S105= | Silent (SNP) | VAF 23/204 reads (11%) | catalogued as rs374087257; called by muse, mutect2, varscan2
- PIP | c.336C>G p.A112= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as rs367785031, COSV99344206; called by muse, mutect2, varscan2
- PITX1 | c.909G>A p.P303= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs772730554, COSV99530686; called by muse, mutect2, varscan2
- RELB | c.375G>A p.P125= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs746034758, COSV99673057; called by muse, mutect2, varscan2
- SERPINH1 | c.546C>T p.D182= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as rs748359784, COSV100825123; called by muse, mutect2, varscan2
- SLC24A4 | c.1128C>T p.N376= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs373277264; called by muse, mutect2, varscan2
- SPATS2L | c.747C>A p.S249= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100660811; called by muse, mutect2, varscan2
- TAF1 | c.2262G>A p.R754= (on ENST00000373790 / NM_138923.4; = p.R775= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as COSV99336396; called by muse, mutect2, varscan2
- TTN | c.12804T>C p.T4268= (on ENST00000591111; = p.T4222= on NM_003319.4) | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV100621306; called by muse, mutect2, varscan2
- VEGFB | c.399G>T p.V133= | Silent (SNP) | VAF 41/174 reads (24%) | catalogued as COSV100374875; called by muse, mutect2, varscan2
- DLG2 | c.205-65783G>T | Intron (SNP) | VAF 117/288 reads (41%) | catalogued as rs45482499, COSV54634359, COSV99717820; called by muse, mutect2, varscan2
- NXF5 | n.982G>A | RNA (SNP) | VAF 10/111 reads (9%) | catalogued as rs1251854263, COSV99534521; called by muse, mutect2, varscan2
